Somatic mutation profile of tumor specimen TCGA-21-1071-01A (aliquot TCGA-21-1071-01A-01D-1521-08) from TCGA case TCGA-21-1071, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.1 years (24,515 days).
Specimen TCGA-21-1071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 094f65f7-8aa8-4a47-8e98-60a2fbfa6ee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1071-11A (Solid Tissue Normal), aliquot TCGA-21-1071-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65f3a774-69d5-4335-bf00-43d1a00f9902

The open-access MAF lists 179 somatic variants for this specimen: 144 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 33, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 4, 3'Flank 1, Translation Start Site 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.239C>A p.T80K | Missense Mutation (SNP) | VAF 95/197 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553487947, COSV67960012, COSV67960020, COSV67960088; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 49/132 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS18 | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51399139, COSV51420022; called by muse, mutect2, varscan2
- ADAMTS5 | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.93); catalogued as rs368988798; called by muse, mutect2, varscan2
- ADCY1 | c.3155A>T p.Y1052F | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV52030442; called by muse, mutect2, varscan2
- ADGRL3 | c.3656C>G p.S1219C (on ENST00000506720 / NM_001322402.2; = p.S1151C on NM_015236.6) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV72229476; called by muse, mutect2, varscan2
- ADGRV1 | c.11620A>G p.I3874V | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs770916018, COSV67978977; called by muse, mutect2
- AFAP1L1 | c.1179G>C p.K393N | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs756369175, COSV57043901; called by muse, mutect2
- ALMS1 | c.8089C>T p.H2697Y | Missense Mutation (SNP) | VAF 52/389 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs956487104, COSV52503299; called by muse, mutect2, varscan2
- ANKAR | c.1747T>G p.L583V | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55609709; called by muse, mutect2, varscan2
- ARHGEF2 | c.647C>G p.S216C (on ENST00000361247 / NM_001162383.2; = p.S188C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58106830; called by muse, mutect2
- BCL2A1 | c.401T>G p.I134R | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51212896, COSV99144359; called by muse, mutect2
- BMS1 | c.792G>T p.L264F | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65732914; called by muse, mutect2
- BRF2 | c.115del p.V39Sfs*15 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs757254105; called by mutect2, pindel, varscan2
- BRPF1 | c.3553C>T p.R1185C | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100115492, COSV57351437; called by muse, mutect2
- C1QTNF6 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV55395746, COSV55396920; called by muse, mutect2, varscan2
- CASD1 | c.1444A>G p.K482E | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51970784; called by muse, mutect2
- CCN3 | c.705T>G p.C235W | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52383113; called by muse, mutect2
- CD300LB | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58725110, COSV58725123; called by muse, mutect2
- CPS1 | c.3374C>A p.P1125H | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51802653; called by muse, varscan2
- CRB1 | c.3307G>C p.G1103R | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as CM040718, CM057655, COSV100958048, COSV66328782, COSV66330317; called by muse, mutect2, varscan2
- CRY1 | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1361980808, COSV50481114; called by muse, mutect2
- CRYBA4 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61321326; called by muse, mutect2
- CSMD3 | c.9872G>A p.C3291Y (on ENST00000297405 / NM_001363185.1; = p.C3122Y on NM_052900.3) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330141465, COSV52107992, COSV52358454; called by muse, varscan2
- CSPP1 | c.2668A>G p.I890V (on ENST00000676605; = p.I849V on NM_024790.6) | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs932817255, COSV51580462; called by muse, mutect2, varscan2
- CYB5R4 | c.549A>G p.I183M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1386300386, COSV63750150; called by muse, mutect2, varscan2
- DCAF4L2 | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100150553; called by mutect2, varscan2
- DNAH2 | c.5288T>G p.F1763C | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66716643; called by muse, mutect2, varscan2
- DNAH7 | c.12026A>C p.E4009A | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV56752926; called by muse, mutect2, varscan2
- DOCK4 | c.2915G>T p.R972L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs750882888, COSV70233780; called by muse, mutect2
- DPEP2 | c.1369C>G p.P457A | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV52053842; called by muse, varscan2
- DYSF | c.4133C>T p.P1378L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50270045, COSV99249124; called by muse, varscan2
- EMC2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs749642246, COSV55207965; called by muse, mutect2, varscan2
- EML5 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); catalogued as COSV61342099; called by muse, mutect2, varscan2
- F2R | c.932C>A p.A311D | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59928486; called by muse, mutect2
- FANCB | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV60758904; called by muse, mutect2, varscan2
- FBN2 | c.2317G>C p.A773P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52494356; called by muse, mutect2, varscan2
- FLG2 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 39/655 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.748); catalogued as COSV66166783; called by muse, mutect2
- FLT4 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56099015; called by muse, mutect2, varscan2
- G6PC | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV53830166, COSV53830614; called by muse, mutect2, varscan2
- GABPA | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.082); catalogued as COSV61395448; called by muse, mutect2, varscan2
- GJA10 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65354801; called by muse, mutect2
- GLI1 | c.2458T>G p.C820G | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.986); catalogued as COSV99953755; called by mutect2, varscan2
- GLYATL1 | c.781C>T p.P261S (on ENST00000317391 / NM_001354699.1; = p.P292S on NM_080661.4) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55607273; called by muse, mutect2, varscan2
- GNPDA2 | c.495T>G p.D165E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); catalogued as COSV54946055; called by muse, mutect2, varscan2
- GON4L | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55187445; called by muse, mutect2, varscan2
- GOT2 | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55330804; called by muse, mutect2, varscan2
- GPR152 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV100351542, COSV56885123; called by muse, mutect2, varscan2
- H2BC13 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV62440465; called by muse, mutect2, varscan2
- HOXB8 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53309879; called by muse, mutect2
- HSPA12A | c.620G>A p.W207* | Nonsense Mutation (SNP) | VAF 73/245 reads (30%) | catalogued as COSV65020884; called by muse, mutect2, varscan2
- IGSF11 | c.653C>G p.S218C (on ENST00000393775 / NM_001015887.3; = p.S217C on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61165876; called by muse, mutect2
- IQGAP2 | c.2840T>C p.I947T | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57168296; called by muse, mutect2, varscan2
- IQGAP3 | c.2674G>C p.E892Q | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs768517691, COSV63249522; called by muse, mutect2, varscan2
- ITPRID1 | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.069); catalogued as COSV60070448; called by muse, mutect2, varscan2
- KCNH4 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1365185558, COSV52915450; called by muse, mutect2
- KCNT2 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV54065078, COSV99657109; called by muse, mutect2
- KIF24 | c.800A>C p.Q267P | Missense Mutation (SNP) | VAF 27/313 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61453285; called by muse, mutect2
- KMT5B | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV58563864; called by muse, mutect2, varscan2
- LILRA6 | c.845C>A p.T282N | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV54429825; called by muse, mutect2, varscan2
- LPCAT3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs782492797, COSV54644836; called by muse, mutect2, varscan2
- LRRC7 | c.2297C>A p.P766Q (on ENST00000651989 / NM_001370785.2; = p.P733Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50413157; called by muse, mutect2
- LYAR | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1299597889, COSV58642192; called by muse, mutect2, varscan2
- LYNX1 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100235640, COSV59988060; called by muse, mutect2, varscan2
- MAB21L1 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV59761902; called by muse, mutect2, varscan2
- MACF1 | c.4252-1G>C p.X1418_splice | Splice Site (SNP) | VAF 5/58 reads (9%) | catalogued as COSV58360532; called by muse, mutect2
- MED23 | c.417A>C p.K139N | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV63430296; called by muse, mutect2, varscan2
- MET | c.3287C>G p.T1096S | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs45592846, COSV59257129; called by muse, mutect2
- MIS18BP1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100172748, COSV60369211; called by muse, mutect2, varscan2
- MTRR | c.8C>G p.A3G | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV52941829, COSV52948066; called by muse, mutect2, varscan2
- MYBPH | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as COSV55137187; called by muse, mutect2, varscan2
- NBPF1 | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1175286302; called by muse, varscan2
- NFKB2 | c.1183A>G p.M395V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV50041907; called by muse, mutect2, varscan2
- NFKBIZ | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1397074896, COSV58199513; called by muse, mutect2
- NID2 | c.2908C>A p.L970M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.657); catalogued as COSV53493228; called by muse, mutect2, varscan2
- NISCH | c.2752A>T p.N918Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV61898601; called by muse, mutect2, varscan2
- NRXN2 | c.3071C>A p.T1024K | Missense Mutation (SNP) | VAF 57/307 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs757534789, COSV55447700; called by muse, mutect2, varscan2
- OPRL1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61091003; called by muse, mutect2, varscan2
- OR10G7 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57865675; called by muse, mutect2
- OR4C13 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV73648638; called by muse, mutect2
- OR4F15 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 13/194 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59968285; called by muse, mutect2
- OR52W1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60950455; called by muse, mutect2, varscan2
- OR8H1 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 83/389 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57293080; called by muse, mutect2, varscan2
- PCDH8 | c.1853C>A p.S618Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58810920; called by muse, mutect2
- PCDHB3 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.637); catalogued as COSV50564367; called by muse, mutect2
- PCDHGA3 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 84/264 reads (32%) | catalogued as COSV53902853, COSV54066637; called by muse, mutect2, varscan2
- PCM1 | c.840T>A p.H280Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61514842; called by muse, mutect2, varscan2
- PDE1A | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV59515074; called by muse, mutect2, varscan2
- PILRA | c.790-1G>C p.X264_splice | Splice Site (SNP) | VAF 10/170 reads (6%) | catalogued as COSV52199255; called by muse, mutect2
- PSG5 | c.266A>T p.N89I | Missense Mutation (SNP) | VAF 249/478 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745773766, COSV61653557; called by muse, mutect2, varscan2
- PTPN23 | c.3209G>A p.R1070Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs762143288, COSV99650258; called by mutect2, varscan2
- RAB11FIP1 | c.3115G>T p.V1039L | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV54758308; called by muse, mutect2
- RALGAPB | c.195G>T p.W65C | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53434574; called by muse, mutect2, varscan2
- RNF114 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54868754; called by muse, mutect2, varscan2
- ROBO2 | c.706G>C p.V236L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.362); catalogued as COSV59898147; called by muse, mutect2, varscan2
- RP1 | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV55110588; called by muse, mutect2, varscan2
- RP1L1 | c.6591G>T p.E2197D | Missense Mutation (SNP) | VAF 103/557 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV66751966; called by muse, mutect2, varscan2
- RP1L1 | c.2387C>A p.A796D | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV66751968; called by muse, mutect2, varscan2
- RSAD1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.037); catalogued as COSV51954752, COSV99364111; called by muse, mutect2
- RYR2 | c.8814G>C p.Q2938H | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV63663883, COSV99053505; called by muse, mutect2, varscan2
- SCG5 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55705262; called by muse, mutect2
- SERPINF2 | c.411C>A p.H137Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100131623, COSV60663587; called by muse, mutect2, varscan2
- SETD1A | c.4838G>A p.R1613H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs765554192, COSV52679658; called by muse, mutect2, varscan2
- SETD5 | c.2692G>A p.A898T | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs774430004, COSV56707677; called by muse, mutect2, varscan2
- SGK2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.309); catalogued as COSV58312161; called by muse, mutect2, varscan2
- SHC2 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV52743892; called by muse, mutect2
- SIRT6 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV50173533; called by muse, mutect2, varscan2
- SKAP2 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61721550; called by muse, varscan2
- SLC15A2 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 73/500 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs1339657136, COSV55196096; called by muse, mutect2, varscan2
- SLC25A33 | c.57-2A>C p.X19_splice | Splice Site (SNP) | VAF 8/99 reads (8%) | catalogued as COSV57019166; called by muse, mutect2
- SLC27A2 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.633); catalogued as COSV51057522; called by muse, mutect2, varscan2
- SLC35G1 | c.844G>A p.G282R (on ENST00000427197 / NM_001134658.3; = p.G281R on NM_153226.4) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV65055058, COSV65055726; called by muse, mutect2
- SLITRK2 | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59423265, COSV59428303; called by muse, mutect2, varscan2
- SNX20 | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56056681; called by muse, mutect2, varscan2
- SPHKAP | c.36C>A p.N12K | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60869216; called by muse, mutect2, varscan2
- SSH2 | c.2935C>A p.Q979K | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52166885; called by muse, mutect2, varscan2
- STAP1 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99609193; called by muse, mutect2, varscan2
- SUPT20H | c.899T>A p.L300* (on ENST00000350612 / NM_001014286.3; = p.L301* on NM_017569.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV62246854; called by muse, mutect2, varscan2
- TASP1 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV61811482; called by muse, mutect2
- TBK1 | c.813-1G>T p.X271_splice | Splice Site (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100538042; called by muse, mutect2, varscan2
- TENM3 | c.42G>C p.K14N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1390946372, COSV69299825; called by muse, mutect2
- TMC5 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs774931297, COSV66864553; called by muse, mutect2, varscan2
- TMEM87B | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); catalogued as rs1415117062, COSV51712905; called by muse, mutect2, varscan2
- TMTC3 | c.2637C>A p.D879E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV57122434, COSV99898802; called by muse, mutect2, varscan2
- TMTC3 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199847201, COSV57122444; called by muse, mutect2, varscan2
- TREML2 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.261); catalogued as COSV101530194, COSV72439024; called by muse, mutect2, varscan2
- TTBK1 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV52488358, COSV99445067; called by muse, mutect2, varscan2
- TTPA | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV52645847, COSV99478420; called by muse, mutect2, varscan2
- UNC13A | c.2081C>A p.T694K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53188794; called by muse, mutect2, varscan2
- UNC13A | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs139378806, COSV53188816; called by muse, mutect2, varscan2
- VPS13A | c.2356A>G p.M786V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62425469; called by muse, mutect2, varscan2
- WNK1 | c.3758C>T p.S1253F (on ENST00000315939 / NM_018979.4; = p.S1006F on NM_014823.3) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60026017; called by muse, mutect2, varscan2
- WNK3 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV63612192; called by muse, mutect2, varscan2
- ZDBF2 | c.3575A>G p.N1192S | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV65622078; called by muse, mutect2, varscan2
- ZFAND1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV55106720; called by muse, mutect2, varscan2
- ZFHX4 | c.7135C>A p.P2379T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51449413; called by muse, mutect2, varscan2
- ZNF230 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71273235; called by muse, mutect2, varscan2
- ZNF311 | c.743A>C p.E248A | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as COSV65852856; called by muse, mutect2, varscan2
- ALMS1 | c.7795del p.R2599Dfs*14 | Frame Shift Del (DEL) | VAF 44/184 reads (24%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.205); called by muse, mutect2
- FOXD4L5 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.146); called by muse, varscan2
- KMT2D | c.12625_12626del p.P4209Tfs*124 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- PGAP6 | c.1148_1162del p.P383_R387del | In Frame Del (DEL) | VAF 6/76 reads (8%) | called by mutect2, pindel
- PRX | c.3785_3818del p.E1262Afs*109 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel
- ADGRL4 | c.711C>T p.S237= | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as COSV66059504; called by muse, mutect2
- ALDH16A1 | c.858C>T p.D286= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV53192723; called by muse, mutect2, varscan2
- CAMKMT | c.366A>T p.T122= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as COSV65923580; called by muse, mutect2, varscan2
- CARD14 | c.2271C>A p.T757= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100712493; called by muse, mutect2
- CHD5 | c.4161G>A p.P1387= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as rs773893368, COSV52408168; called by muse, mutect2, varscan2
- ERCC6L | c.960C>A p.I320= | Silent (SNP) | VAF 70/157 reads (45%) | catalogued as COSV57819451; called by muse, mutect2, varscan2
- FHL5 | c.408T>C p.P136= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV58735263; called by muse, mutect2, varscan2
- FLT4 | c.3063G>A p.V1021= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as rs755012542, COSV56098994; called by muse, mutect2
- GABRG2 | c.90G>T p.L30= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs115976622, COSV62715630; called by muse, mutect2, varscan2
- GMEB2 | c.1401G>T p.T467= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV99823478, COSV99823676; called by muse, mutect2, varscan2
- GPC4 | c.1479T>C p.S493= | Silent (SNP) | VAF 119/224 reads (53%) | catalogued as COSV63696939; called by muse, mutect2, varscan2
- HAPLN1 | c.453G>T p.V151= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as COSV57145540; called by muse, mutect2, varscan2
- KRT33B | c.246G>A p.A82= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as rs201559637, COSV52440218; called by muse, mutect2, varscan2
- MAG | c.1722G>A p.E574= | Silent (SNP) | VAF 101/371 reads (27%) | catalogued as COSV62699040; called by muse, mutect2, varscan2
- MYOT | c.939C>A p.V313= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV99524787; called by muse, mutect2
- OR51L1 | c.648A>T p.I216= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV58623945; called by muse, mutect2, varscan2
- OR5B12 | c.870G>C p.L290= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as rs1182994357, COSV56904024; called by muse, mutect2
- PCDHGA5 | c.660G>A p.P220= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV53902875, COSV99549074; called by muse, mutect2
- PHF10 | c.732A>C p.P244= | Silent (SNP) | VAF 41/203 reads (20%) | catalogued as COSV59321085; called by muse, mutect2, varscan2
- PITX2 | c.943C>A p.R315= (on ENST00000354925 / NM_001204397.1; = p.R322= on NM_000325.6) | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100146222, COSV100146291, COSV60741638; called by muse, mutect2, varscan2
- PJVK | c.678C>T p.V226= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV64306211; called by muse, varscan2
- PLD2 | c.1776C>T p.L592= | Silent (SNP) | VAF 51/206 reads (25%) | catalogued as COSV54003590; called by muse, mutect2, varscan2
- PROP1 | c.198G>A p.P66= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs769315766, COSV57644591; called by muse, mutect2, varscan2
- RENBP | c.294T>G p.G98= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV60069597; called by muse, mutect2, varscan2
- SLC25A43 | c.675G>A p.V225= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as COSV54216914; called by muse, mutect2, varscan2
- SLC26A4 | c.1752G>A p.A584= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs771015634, COSV55914542; ClinVar: likely benign; called by muse, varscan2
- SLC36A2 | c.1152C>T p.S384= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV58862147; called by muse, mutect2
- TESK1 | c.930C>T p.H310= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs1478633366, COSV52410279; called by muse, mutect2, varscan2
- THBS4 | c.1224G>A p.P408= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs548126974, COSV63467797; called by muse, mutect2, varscan2
- UNC13C | c.372G>A p.E124= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV52845555; called by muse, mutect2, varscan2
- UNC5D | c.219C>G p.L73= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV54771463; called by muse, mutect2, varscan2
- ZFAND2A | c.114A>G p.P38= | Silent (SNP) | VAF 76/350 reads (22%) | catalogued as rs1002227737, COSV57179941; called by muse, mutect2, varscan2
- ZFAT | c.1206G>A p.L402= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV64734700; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506380 T>C | 3'Flank (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- PNCK | c.539-41G>A | Intron (SNP) | VAF 35/60 reads (58%) | catalogued as rs149305071, COSV100562205; called by muse, mutect2, varscan2
